Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GT, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GT-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:
Reported:
Submitting Physicians:
Pathologist:
Intrapathologist:
Performing Physician:

CLINICAL HISTORY:
POSITIVE SMOKER, POSITIVE ETOH, CIRRHOSIS, ELEVATED LFT AND ELEVATED AST, POSITIVE
HEPATITIS A (H-C STILL PENDING).

PREOPERATIVE DIAGNOSIS:
HEPATOCELLULAR CARCINOMA.

SPECIMEN TYPE(S):
A: GALLBLADDER
B: SEGMENT 5 LIVER FS.

FINAL DIAGNOSIS:
A. GALLBLADDER, CHOLECYSTECTOMY:
Cholelithiasis.
B. LIVER, SEGMENT 5, EXCISION:
Hepatocellular carcinoma, moderately differentiated (see Key Pathological
Findings).

KEY PATHOLOGICAL FINDINGS

Specimen type:	Hepatic segmentectomy	
Tumor site:	Liver, segment 5	5% clear cell, per TSS
Histologic type:	Hepatocellular carcinoma, with clear cell areas	
Histological grade:	Grade II	
Tumor size:	5.5 cm	
Vascular invasion:	Not identified	
Angiolymphatic invasion:	Not identified	
Resection margin:	Free of tumor	
Capsular surface:	Not involved	
Non-neoplastic parenchyma:	Cirrhosis with evidence of chronic active hepatitis	
Pathologic stage:	TX NX MX	

I, the attending pathologist, personally reviewed the entire
pathology case and rendered the final diagnosis. Electronically signed out by

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:
B. LIVER, SEGMENT 5:
FS. Hepatocellular carcinoma, margin 9 mm from tumor.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by
in at

ICD0-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver NOS
C22.0
4/22/14

[page 2 of 2]
I, _____, have performed the intraoperative consultation and issued the above diagnosis.

GROSS DESCRIPTION:

- A. Specimen A is received fresh labeled "gallbladder". The specimen consists of a previously opened gallbladder measuring 8.2 x 4.0 x 1.5 cm. The serosa of the gallbladder is tan-pink, smooth, glistening and mildly congested. The gallbladder contents consist of a moderate amount of viscous green bile and a single irregular, tan-green, firm gallstone measuring up to 1.5 cm in greatest dimension. The mucosa of the gallbladder is partially velvety and partially honeycombed and stained bile green. The cystic duct is patent to the flow of bile and has a 0.3 cm in diameter lumen. No lymph nodes are identified adjacent to the gallbladder neck. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in three cassettes as follows:
- A1: Tangential section of the resection margin of the cystic duct
- A2: Representative section of the gallbladder body
- A3: Representative section of the fundus of the gallbladder
- B. Specimen B is received fresh labeled "segment 5 liver". The specimen consists of a 175 g, 10.5 x 7.5 x 5.5 cm fragment of liver parenchyma. The capsular surface of the specimen is variegated, tan, pale yellow to tan-pink, focally hemorrhagic, smooth, glistening and focally bosselated. The surgical margin of resection is grossly unremarkable and inked black. On sectioning, the specimen reveals an irregular, ill-defined soft to rubbery, lobulated tumor mass measuring 5.8 x 4.0 x 4.0 cm which is 0.8 cm from the closest inked black surgical resection margin. The remaining liver parenchyma is tan, red-brown, lobular with multiple subcapsular hemorrhages ranging from 0.1 to 0.2 cm in greatest dimension. Representative section of the specimen with tumor and closest margin of resection is submitted for frozen section as FSA. Additional sections of the specimen are submitted in three cassettes labeled B1-B3.

Source: NCI Genomic Data Commons file fe3790c4-55c6-41ec-a1ed-adf345e36f14 (TCGA-2Y-A9GT.AC6F0803-6F8E-4708-80DE-DFC708B2217D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).